Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAVQ, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAVQ-01A (Primary Tumor).

DIAGNOSIS:

Liver, S6, segmentectomy:

Hepatocellular carcinoma, S6

- 1) Post-chemoembolization status: absent
- 2) Size of tumor: 3.0x3.0x2.2cm
- 3) Gross type: multinodular confluent type
- 4) Satellite nodule: absent
- 5) Histologic type: microtrabecular, macrotrabecular and solid
- 6) Cell type: cirrhotomimetic and clear
- 7) Edmondson and Steiner's histologic grade:
The worst differentiation: 3
The major differentiation: 2
- 8) Fatty change: present (1%)
- 9) Hemorrhage/petiosis: present (1%)
- 10) Tumor necrosis: absent
- 11) Vascular invasion(microscopic): absent
- 12) Capsule formation: complete
- 13) Infiltration of capsule: absent
- 14) Septal formation: present
- 15) Involvement of a major branch of the portal vein: absent
- 16) Involvement of a major branch of the hepatic vein: absent
- 17) Bile duct invasion: absent
- 18) Serosal invasion: absent
- 19) Surgical margin: negative (safety margin: 2.1cm)
- 20) Intrahepatic metastasis: absent
- 21) Multicentric occurrence: absent
- 22) Pathologic stage: AJCC (pT1). (pT2)
- 23) Related biopsy: none
- 24) Additional pathologic findings
- a) Cirrhosis: present, active
- b) Dysplasia: absent

ICD-O-3

Carcinoma, hepatocellular NOS
817013

Site Liver C22.0

9104122/14

Source: NCI Genomic Data Commons file d1944d41-2306-4dbd-9008-6c083184c695 (TCGA-DD-AAVQ.A58E32BF-829C-48AB-BC80-919A295D78D5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).